Somatic mutation profile of tumor specimen ALCH-B2VV-TTP1-A (aliquot ALCH-B2VV-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2VV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.7 years (26,195 days).
Specimen ALCH-B2VV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86d0dc0c-13cb-4299-988a-4a697a9b1139.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2VV-NB1-A (Blood Derived Normal), aliquot ALCH-B2VV-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f1e90d8-67a4-4d41-ac55-1433442db125

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.821A>T p.H274L | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV50264820, COSV50277923; called by muse, mutect2
- KLHL4 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs751855180, COSV64141978; called by muse, mutect2
- OR7G2 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 9/301 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as COSV59687755; called by muse, mutect2
- ATG2A | c.4430A>T p.Q1477L | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.104); called by muse, mutect2
- TCF12 | c.1060A>T p.S354C | Missense Mutation (SNP) | VAF 14/437 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- ESRP1 | c.111C>G p.V37= | Silent (SNP) | VAF 11/270 reads (4%) | called by muse, mutect2
- GCC2 | c.3906A>G p.L1302= | Silent (SNP) | VAF 9/245 reads (4%) | called by muse, mutect2
- UGCG | c.546C>T p.A182= | Silent (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
